Somatic mutation profile of tumor specimen C3N-00517-01 (aliquot CPT0093860009) from CPTAC case C3N-00517, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.6 years (25,407 days).
Specimen C3N-00517-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3ab17c9-d320-4010-acb4-8166172fb3db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00517-31 (Blood Derived Normal), aliquot CPT0093920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b81f4ab-a336-42f3-b980-fa3b767245e2

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290122973; called by muse, mutect2
- CACNA1H | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs932161061; ClinVar: uncertain significance; called by muse, mutect2
- HMCN1 | c.10699C>T p.R3567W | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382158216; called by muse, mutect2
- RNF180 | c.1512C>A p.S504R | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV101205071; called by muse, mutect2
- CEP162 | c.1872T>C p.D624= | Silent (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
- KCNA4 | c.1230C>A p.V410= | Silent (SNP) | VAF 10/217 reads (5%) | catalogued as COSV100069354; called by muse, mutect2
- LRP8 | c.582C>T p.D194= | Silent (SNP) | VAF 14/429 reads (3%) | called by muse, mutect2
- CACNA1S | c.*31C>T | 3'UTR (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- LATS1 | c.-338C>T | 5'UTR (SNP) | VAF 10/57 reads (18%) | catalogued as rs975219609; called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1419C>G | RNA (SNP) | VAF 26/763 reads (3%) | called by muse, mutect2
